Somatic mutation profile of tumor specimen C3N-01192-05 (aliquot CPT0087950009) from CPTAC case C3N-01192, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 60.1 years (21,957 days).
Specimen C3N-01192-05: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Frontal Lobe; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ace0df58-6655-4fcf-8a95-19373de68582.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01192-31 (Blood Derived Normal), aliquot CPT0087980002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3e928238-2092-41e2-a649-eb70523a30d8

The open-access MAF lists 97 somatic variants for this specimen: 66 protein-altering or splice-affecting, 21 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 59, Silent 21, Intron 5, Nonsense Mutation 3, Frame Shift Del 2, Splice Site 1, Splice Region 1, 3'Flank 1, RNA 1, 5'UTR 1, 5'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARC | c.662T>A p.L221Q | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV63078544; called by muse, mutect2, varscan2
- CACNG3 | c.622C>T p.R208* | Nonsense Mutation (SNP) | VAF 46/278 reads (17%) | catalogued as COSV50082807; called by muse, varscan2
- CDH10 | c.1315G>A p.G439R | Missense Mutation (SNP) | VAF 105/374 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52576797; called by muse, mutect2, varscan2
- COBL | c.1661C>T p.S554L | Missense Mutation (SNP) | VAF 67/341 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs776611376, COSV54360636; called by muse, mutect2, varscan2
- CPNE7 | c.1639G>A p.V547M | Missense Mutation (SNP) | VAF 42/178 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778892669; called by muse, mutect2, varscan2
- CYSLTR1 | c.748C>T p.H250Y | Missense Mutation (SNP) | VAF 74/389 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64819557; called by muse, mutect2, varscan2
- DMD | c.5996C>A p.T1999N | Missense Mutation (SNP) | VAF 90/530 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.085); catalogued as COSV100822816; called by muse, mutect2, varscan2
- DYSF | c.4025G>A p.R1342Q | Missense Mutation (SNP) | VAF 148/510 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747583441, COSV50556740; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EPB41L1 | c.1606C>T p.R536C | Missense Mutation (SNP) | VAF 113/488 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs757708154; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FANCB | c.2181G>A p.M727I | Missense Mutation (SNP) | VAF 106/306 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as COSV60759626; called by muse, mutect2, varscan2
- FIS1 | c.235G>A p.V79M | Missense Mutation (SNP) | VAF 120/504 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as rs768025810, COSV56191136; called by muse, mutect2, varscan2
- FJX1 | c.740C>A p.P247H | Missense Mutation (SNP) | VAF 104/296 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.159); catalogued as COSV58552965; called by muse, mutect2, varscan2
- GRIN2B | c.2707C>T p.R903C | Missense Mutation (SNP) | VAF 112/334 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs369045170, COSV101663129; called by muse, mutect2, varscan2
- KLHL34 | c.635G>A p.R212H | Missense Mutation (SNP) | VAF 68/377 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as rs1432124735; called by muse, mutect2, varscan2
- KMT2C | c.7490G>A p.R2497H | Missense Mutation (SNP) | VAF 42/194 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.012); catalogued as rs531219111, COSV51471176; called by muse, mutect2
- LAMA2 | c.2049A>T p.R683S | Missense Mutation (SNP) | VAF 178/672 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0.014); catalogued as CD982727; called by muse, mutect2, varscan2
- MIA2 | c.1655C>T p.S552L | Missense Mutation (SNP) | VAF 92/366 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.168); catalogued as rs754149612, COSV54482945; called by muse, mutect2, varscan2
- NAT14 | c.485G>A p.R162Q | Missense Mutation (SNP) | VAF 38/133 reads (29%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.375); catalogued as rs1359701141; called by muse, mutect2, varscan2
- NEB | c.2743G>A p.V915I | Missense Mutation (SNP) | VAF 90/278 reads (32%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.457); catalogued as rs758639063; called by muse, mutect2, varscan2
- NID2 | c.2950G>A p.V984M | Missense Mutation (SNP) | VAF 56/233 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs772923728, COSV53493033; called by muse, mutect2, varscan2
- NLRP6 | c.1904G>A p.R635H | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT tolerated (0.5); PolyPhen benign (0.005); catalogued as rs145289554; called by muse, mutect2, varscan2
- NMRK2 | c.91G>A p.V31M | Missense Mutation (SNP) | VAF 54/246 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as rs376394284; called by muse, mutect2, varscan2
- NOBOX | c.1079G>A p.R360Q | Missense Mutation (SNP) | VAF 31/149 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs199538689, COSV56197973; ClinVar: likely benign; called by muse, mutect2, varscan2
- NTRK1 | c.23G>A p.G8E | Missense Mutation (SNP) | VAF 58/228 reads (25%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs1221586997; called by muse, mutect2, varscan2
- OR7C2 | c.524C>T p.P175L | Missense Mutation (SNP) | VAF 136/687 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.168); catalogued as rs201250660, COSV50181428; called by muse, mutect2, varscan2
- PHEX | c.59G>A p.R20Q | Missense Mutation (SNP) | VAF 152/714 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs1164800764, COSV65080219; called by muse, mutect2, varscan2
- PRAMEF6 | c.712G>A p.V238I | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs761497343; called by mutect2, varscan2
- RASSF5 | c.1051G>A p.D351N | Missense Mutation (SNP) | VAF 79/283 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0.086); catalogued as rs782292608; called by muse, mutect2, varscan2
- RECK | c.2831G>A p.G944D | Missense Mutation (SNP) | VAF 109/360 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.031); catalogued as rs771396594; called by muse, mutect2, varscan2
- SIRT4 | c.290G>A p.R97Q | Missense Mutation (SNP) | VAF 77/285 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.087); catalogued as rs1303583748, COSV52542072; called by muse, mutect2, varscan2
- SLC45A3 | c.1600G>A p.A534T | Missense Mutation (SNP) | VAF 81/278 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs776481406; called by muse, mutect2, varscan2
- THSD4 | c.199C>T p.R67C | Missense Mutation (SNP) | VAF 35/149 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV104380097; called by muse, mutect2, varscan2
- TMEM150B | c.613G>A p.A205T | Missense Mutation (SNP) | VAF 68/388 reads (18%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs759105710, COSV58594106; called by muse, mutect2, varscan2
- TRNAU1AP | c.464C>T p.T155M | Missense Mutation (SNP) | VAF 90/295 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.52); catalogued as rs768909623; called by muse, mutect2, varscan2
- USH2A | c.9352A>G p.I3118V | Missense Mutation (SNP) | VAF 150/542 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV100233208; called by muse, mutect2, varscan2
- XPNPEP2 | c.925C>T p.R309C | Missense Mutation (SNP) | VAF 116/569 reads (20%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.724); catalogued as rs151254296, COSV100941354, COSV64369455; called by muse, mutect2, varscan2
- ADH6 | c.518T>C p.I173T | Missense Mutation (SNP) | VAF 137/476 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.357); called by muse, mutect2, varscan2
- ARNT | c.251C>G p.A84G | Missense Mutation (SNP) | VAF 86/292 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.301); called by muse, varscan2
- BHMG1 | c.670C>A p.P224T | Missense Mutation (SNP) | VAF 165/724 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- CBLL2 | c.1155G>A p.M385I | Missense Mutation (SNP) | VAF 118/542 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNMBP | c.3395A>T p.Y1132F | Missense Mutation (SNP) | VAF 143/347 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.596); called by muse, mutect2, varscan2
- EGF | c.1439-1G>A p.X480_splice | Splice Site (SNP) | VAF 162/560 reads (29%) | called by muse, mutect2, varscan2
- FBN3 | c.3232G>A p.D1078N | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT tolerated (0.58); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- FPR1 | c.514G>A p.G172R | Missense Mutation (SNP) | VAF 138/601 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- GGA2 | c.1129G>A p.G377R | Missense Mutation (SNP) | VAF 61/217 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- GNAS | c.274G>A p.V92M | Missense Mutation (SNP) | VAF 271/1193 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.421); called by muse, mutect2, varscan2
- GPAA1 | c.513G>A p.R171= | Splice Region (SNP) | VAF 55/273 reads (20%) | called by muse, mutect2, varscan2
- LAMB1 | c.2602C>T p.Q868* | Nonsense Mutation (SNP) | VAF 92/483 reads (19%) | called by muse, mutect2, varscan2
- MAGIX | c.502T>G p.L168V | Missense Mutation (SNP) | VAF 39/163 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- MANEA | c.748G>A p.A250T | Missense Mutation (SNP) | VAF 40/144 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- MATK | c.301G>A p.A101T (on ENST00000310132 / NM_139355.3; = p.A102T on NM_002378.4) | Missense Mutation (SNP) | VAF 42/225 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- MFAP3L | c.495G>A p.M165I | Missense Mutation (SNP) | VAF 89/326 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- OR1L4 | c.927T>G p.I309M | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.115); called by muse, varscan2
- OR5H14 | c.626T>A p.F209Y | Missense Mutation (SNP) | VAF 69/265 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- PPP1R13B | c.118G>T p.E40* | Nonsense Mutation (SNP) | VAF 123/343 reads (36%) | called by muse, mutect2, varscan2
- PRKX | c.77G>A p.G26E | Missense Mutation (SNP) | VAF 58/278 reads (21%) | SIFT tolerated (0.65); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- SCN2A | c.1552G>C p.E518Q | Missense Mutation (SNP) | VAF 157/579 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- SCUBE3 | c.20C>A p.P7H | Missense Mutation (SNP) | VAF 41/191 reads (21%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- SOCS5 | c.625del p.H209Ifs*5 | Frame Shift Del (DEL) | VAF 89/378 reads (24%) | called by mutect2, pindel, varscan2
- TICAM1 | c.1249G>C p.E417Q | Missense Mutation (SNP) | VAF 100/356 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.539); called by muse, mutect2, varscan2
- TSBP1 | c.1037C>T p.A346V (on ENST00000617061; = p.A351V on NM_006781.5) | Missense Mutation (SNP) | VAF 83/275 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- ULK4 | c.937G>A p.E313K | Missense Mutation (SNP) | VAF 101/355 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- USP9X | c.7352C>T p.T2451M | Missense Mutation (SNP) | VAF 130/774 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- ZNF280C | c.182T>C p.I61T | Missense Mutation (SNP) | VAF 49/238 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- ZNF292 | c.1920_1921del p.Y641Ffs*8 | Frame Shift Del (DEL) | VAF 81/312 reads (26%) | called by pindel, varscan2
- ZNF844 | c.1823C>T p.T608I | Missense Mutation (SNP) | VAF 60/282 reads (21%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.217); called by muse, mutect2, varscan2
- ABCA2 | c.2718C>T p.I906= (on ENST00000614293; = p.I876= on NM_001606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 153/418 reads (37%) | catalogued as rs749410154, COSV99688300; called by muse, mutect2, varscan2
- AK7 | c.318C>G p.L106= | Silent (SNP) | VAF 26/132 reads (20%) | called by muse, mutect2, varscan2
- ARMC10 | c.189C>T p.A63= | Silent (SNP) | VAF 26/159 reads (16%) | called by muse, mutect2, varscan2
- CUL9 | c.4815C>T p.L1605= | Silent (SNP) | VAF 44/182 reads (24%) | catalogued as COSV52732568; called by muse, mutect2, varscan2
- DSG4 | c.231C>T p.C77= | Silent (SNP) | VAF 87/321 reads (27%) | catalogued as rs200935383; called by muse, mutect2, varscan2
- FAM83C | c.186G>A p.R62= | Silent (SNP) | VAF 158/738 reads (21%) | called by muse, mutect2, varscan2
- IGHD | c.1173C>T p.S391= | Silent (SNP) | VAF 140/500 reads (28%) | catalogued as rs1221604955; called by muse, mutect2, varscan2
- KBTBD7 | c.315C>T p.Y105= | Silent (SNP) | VAF 170/612 reads (28%) | called by muse, mutect2, varscan2
- LAMA1 | c.6219C>T p.D2073= | Silent (SNP) | VAF 164/592 reads (28%) | catalogued as rs751773541, COSV67531675; called by muse, mutect2
- LORICRIN | c.489C>T p.G163= | Silent (SNP) | VAF 79/271 reads (29%) | catalogued as rs1297915161; called by muse, mutect2, varscan2
- MSH3 | c.951C>T p.A317= | Silent (SNP) | VAF 206/606 reads (34%) | called by mutect2, varscan2
- NTN4 | c.927G>A p.P309= | Silent (SNP) | VAF 62/226 reads (27%) | catalogued as rs745601728; called by muse, mutect2, varscan2
- NUSAP1 | c.987C>T p.I329= | Silent (SNP) | VAF 60/264 reads (23%) | called by muse, mutect2, varscan2
- PRKCE | c.1548C>T p.V516= | Silent (SNP) | VAF 86/327 reads (26%) | called by muse, mutect2, varscan2
- PRRT4 | c.2349C>T p.P783= | Silent (SNP) | VAF 62/286 reads (22%) | catalogued as rs1417499516; called by muse, mutect2, varscan2
- RAB11FIP4 | c.1293A>G p.E431= | Silent (SNP) | VAF 83/213 reads (39%) | called by muse, mutect2, varscan2
- S1PR2 | c.678G>A p.P226= | Silent (SNP) | VAF 95/400 reads (24%) | catalogued as rs757657597, COSV58485244; ClinVar: likely benign; called by muse, mutect2, varscan2
- SKOR2 | c.2157C>A p.P719= | Silent (SNP) | VAF 51/212 reads (24%) | called by muse, mutect2
- UBE2NL | c.93C>T p.N31= | Silent (SNP) | VAF 91/450 reads (20%) | catalogued as rs782717601; called by muse, mutect2, varscan2
- WRAP73 | c.282G>A p.L94= | Silent (SNP) | VAF 56/168 reads (33%) | called by muse, mutect2, varscan2
- ZNF524 | c.462C>T p.S154= | Silent (SNP) | VAF 80/385 reads (21%) | called by muse, mutect2, varscan2
- ABCC9 | chr12:21801159 G>A | 3'Flank (SNP) | VAF 160/562 reads (28%) | catalogued as rs554811993, COSV53973652; ClinVar: not provided; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73847956 C>T | 5'Flank (SNP) | VAF 110/605 reads (18%) | called by muse, mutect2, varscan2
- CCDC90B | c.100+12C>T | Intron (SNP) | VAF 66/170 reads (39%) | called by muse, mutect2, varscan2
- F9 | c.*14del | 3'UTR (DEL) | VAF 85/372 reads (23%) | called by mutect2, pindel, varscan2
- HPD | c.93+35C>T | Intron (SNP) | VAF 150/487 reads (31%) | catalogued as rs753060814; called by muse, varscan2
- IDO2 | c.435-494C>A | Intron (SNP) | VAF 18/52 reads (35%) | catalogued as rs557327299; called by muse, varscan2
- LINC00479 | n.359C>T | RNA (SNP) | VAF 88/312 reads (28%) | catalogued as rs887599503; called by muse, mutect2, varscan2
- MFSD9 | c.253+188C>T | Intron (SNP) | VAF 72/258 reads (28%) | catalogued as rs750803748; called by muse, varscan2
- MPI | c.671-34C>T | Intron (SNP) | VAF 61/258 reads (24%) | called by muse, mutect2, varscan2
- TAF1 | c.-53C>T | 5'UTR (SNP) | VAF 93/443 reads (21%) | catalogued as rs765758474, COSV52124434; called by muse, mutect2, varscan2
